Surgical pathology report (de-identified scan), TCGA case TCGA-LB-A8F3, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Candler, specimen TCGA-LB-A8F3-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

LOC: [REDACTED]

AGE/SX: [REDACTED]

ROOM: [REDACTED]

REG DR: [REDACTED]

DOB: [REDACTED]

BED: [REDACTED]

STATUS:

SPEC #: RECD: STATUS: PERFORMED AT [REDACTED]
COLL: TIME IN FORMALIN: hrs.
COLD ISCHEMIA TIME: 0:00 mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Pancreatic mass

Remarks:

- Specimen(s): A. Common bile duct margin
B. Pancreatic duct margin
C. Gallbladder
D. Whipple resection

ICD-O-3

Adenocarcinoma, duct NOS 8500/3

Site: Pancreas head C25.0

JW 5/21/14 JW

MICROSCOPIC DIAGNOSIS

- A. COMMON BILE DUCT MARGIN:
- NO TUMOR SEEN
- B. PANCREATIC DUCT MARGIN:
- NO TUMOR SEEN
- C. HEAD OF PANCREAS, PORTION DUODENUM, PORTION DISTAL STOMACH, PORTION DISTAL BILE DUCT, WHIPPLE RESECTION:
- ADENOCARCINOMA OF HEAD OF PANCREAS, LOW GRADE
- TUMOR MEASURES 5 CM AND INFILTRATES DUODENAL WALL AND PERIPANCREATIC SOFT TISSUE
- SURGICAL MARGINS FREE OF TUMOR WITH NEAREST MARGIN 2 MM FROM TUMOR, PERIPANCREATIC UNCINATE PROCESS
- NO TUMOR SEEN IN ANY OF 10 REGIONAL LYMPH NODES
- SEE COMMENT FOR SYNOPTIC REPORT
- D. GALLBLADDER, CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS
- NO TUMOR SEEN

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - CAP APPROVED

Specimen: Head of pancreas, duodenum, stomach, common bile duct, gallbladder
Procedure: Pancreaticoduodenectomy (whipple resection), partial pancreatectomy
Tumor Site: Pancreatic head
Tumor Size: 5 cm in greatest dimension

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #: (Continued)

COMMENT(S)

(Continued)

Histologic Type: Ductal adenocarcinoma
Histologic Grade: G1
Microscopic Tumor Extension: Tumor invades duodenal wall, tumor invades peripancreatic soft tissue
Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 2 mm; uncinat process, peripancreatic
Treatment Effect: No prior treatment
Pathologic Staging: Primary Tumor: pT3
Regional Lymph Nodes: pN0
Number of lymph nodes: 10
Number involved: 0
Distant Metastasis: Not applicable

GROSS DESCRIPTION:

The specimen is received in multiple parts.

A. The specimen in the fresh state is a portion of dilated duct wall which measures 2 x 1 x 0.3 cm, totally examined by frozen section as block A1.

B. This is a section of pancreas which measures 2 x 1.3 x 0.5 cm. The surgeon has placed a suture on the margin side. Tangential sections through the surgical margin are examined by frozen section as block B1.

C. This specimen in formalin is a dilated gallbladder which measures 11 x 3.5 x 3 cm. The attached cystic duct measures 2 x 1 cm. The serosal surface is smooth and green. Within the lumen is gritty, green sludge. The wall measures 5 mm in thickness. Representative sections are submitted in block C2.

D. This is a whipple resection which measures 15 x 6 x 6 cm and includes: head of pancreas, segment of duodenum, distal portion of stomach, distal portion of dilated common bile duct. The duodenum measures 9 cm in length by 4 cm in diameter. The stomach measures 8 cm in length by 5 cm proximal diameter. Proximal and distal margins are stapled closed. The pancreatic head measures 7 x 4 x 4 cm and contains a firm, relatively circumscribed yellow tumor which measures 5 x 4 x 4 cm. Peripheral margins appear free of tumor. The surgeon has tagged the retroperitoneal margin and I have applied black ink to this margin. I have applied blue ink to the margin of the uncinat process. The common bile duct is dilated and measures 4 x 2 cm. Representative sections of the tumor are submitted for tumor banking. The tumor invades the duodenum wall in the region of the ampulla.

The following sections are submitted:

- D1 - proximal gastric margin
- D2 - distal duodenal margin
- D3 - pancreatic duct margin
- D4-6 - pancreatic tumor with blue ink on uncinat process margin
- D7,8 - pancreatic tumor invading duodenal wall

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #: PATIENT: (Continued)

GROSS DESCRIPTION: (Continued)

- D9 - representative pancreatic tumor
- D10 - retroperitoneal margin, black ink on margin
- D11 - distal pyloric lymph node candidates
- D12 - retroperitoneal lymph node candidates, largest lymph node bisected
- D13 - distal bile duct lymph nodes, largest bisected
- D14 - distal bile duct lymph node, bisected

INTRAOPERATIVE CONSULTATION:

- A. FROZEN SECTION DIAGNOSIS, COMMON BILE DUCT MARGIN:
- NO TUMOR SEEN
- B. FROZEN SECTION DIAGNOSIS, DISTAL PANCREATIC DUCT MARGIN:
- NO TUMOR SEEN
- D. IMMEDIATE GROSS EVALUATION, WHIPPLE RESECTION:
- TUMOR PRESENT IN HEAD OF PANCREAS, PROCESSED FOR TUMOR BANKING
- PERIPHERAL MARGINS GROSSLY FREE OF TUMOR

PHOTO DOCUMENTATION

Image Picture Copy Error
Image Picture Copy Error

Signed ____ (signature on file) ____

** END OF REPORT **

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file 97775058-2b7a-4226-8434-55bb8b345faa (TCGA-LB-A8F3.44BA040E-C349-4D92-AB2B-A271769B466C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).